Gene-level copy-number profile of tumor specimen C3L-06311-05 from CPTAC case C3L-06311, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 67.0 years (24,484 days).
Specimen C3L-06311-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31cc30d2-cec7-4e6b-8624-f715cb47b8e0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06311-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/31c52043-ef79-489b-9c50-d7875c4ec5d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 13,847; copy number 2: 39,557; copy number 3: 3,674; copy number 4: 1,783; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:197,634,315–197,646,017, 2 genes: AC024560.2, AC024560.3.
- chr9:16,473,188–16,476,237, 1 gene (within-gene range 0–2): AL449983.1.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:87,050,202–87,971,930, 27 genes: GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.
- chr10:133,420,666–133,569,835, 8 genes (within-gene range 0–1): SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1.
- chr11:89,177,875–89,499,198, 6 genes: TYR, CBX3P7, AP000720.1, AP000720.2, NOX4, H3P34.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,855,407–16,859,284, 2 genes, copy number 5 (within-gene range 3–5): BX284668.3, MIR3675.
- chr1:16,873,708–16,873,851, 1 gene, copy number 5 (within-gene range 3–5): RNU1-5P.
- chr1:16,889,095–16,889,602, 1 gene, copy number 5 (within-gene range 3–5): BX284668.4.

Autosomal genes at a single copy (total copy number 1): 10,991. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
